Somatic mutation profile of tumor specimen TARGET-10-PARDEY-09A (aliquot TARGET-10-PARDEY-09A-01D) from TARGET case TARGET-10-PARDEY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,059 days).
Specimen TARGET-10-PARDEY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d436a42-3dbb-41f9-872a-0865e9ae0c57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDEY-10A (Blood Derived Normal), aliquot TARGET-10-PARDEY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89ac6b20-9429-42f0-89dd-2cc307cc56eb

The open-access MAF lists 33 somatic variants for this specimen: 17 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 10, Intron 3, In Frame Del 1, RNA 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSN | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56530133; called by muse, mutect2, varscan2
- C1orf94 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as rs1445868579; called by muse, mutect2, varscan2
- FSIP2 | c.1139A>T p.N380I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV58081795; called by muse, mutect2
- GRM7 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs368787807, COSV63139542; called by muse, mutect2, varscan2
- HCN1 | c.819G>T p.R273S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV57497745; called by muse, mutect2, varscan2
- MUC5AC | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.12); catalogued as rs747675063; called by muse, mutect2, varscan2
- OTOR | c.102T>G p.D34E | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs534633227; called by muse, mutect2, varscan2
- PGK2 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs865897397, COSV100505383, COSV59163146; called by muse, mutect2, varscan2
- ADGRD2 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- DNAH12 | c.4405G>A p.D1469N (on ENST00000351747; = p.D1492N on NM_001366028.2) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLG | c.12092A>T p.Y4031F | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- LRP4 | c.3026A>T p.E1009V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCDHGA7 | c.2252A>G p.Q751R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RNF224 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SAMD4A | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBE2J2 | c.566_577del p.V189_D192del | In Frame Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, varscan2
- ZC3H18 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP61 | c.2703G>A p.A901= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV55630337; called by muse, mutect2, varscan2
- CPVL | c.693C>T p.N231= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs147609298, COSV99606600; called by muse, mutect2, varscan2
- MKRN3 | c.258G>A p.P86= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs992964077, COSV100090600, COSV58809496; called by muse, mutect2, varscan2
- MRC2 | c.342G>A p.R114= | Silent (SNP) | VAF 55/128 reads (43%) | called by muse, mutect2, varscan2
- OR5R1 | c.18C>T p.I6= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV56571587; called by muse, mutect2, varscan2
- PCDH11X | c.927C>T p.I309= | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- PXDNL | c.2835G>A p.A945= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs533962228, COSV62501917; called by muse, mutect2, varscan2
- SERPINB11 | c.1095C>T p.F365= | Silent (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- SGCG | c.303A>T p.S101= | Silent (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.1914A>G p.K638= | Silent (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- DNAJC12 | c.297+25T>G | Intron (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- HYDIN2 | n.847G>A | RNA (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- PPP1R42 | c.435+15G>A | Intron (SNP) | VAF 5/65 reads (8%) | catalogued as COSV61208895; called by muse, mutect2
- RABL2A | c.137+153C>T | Intron (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- RNY3P11 | chr6:109307997 C>T | 3'Flank (SNP) | VAF 40/106 reads (38%) | catalogued as rs1020843999; called by muse, mutect2, varscan2
- SLC10A2 | c.*104G>C | 3'UTR (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99808050; called by muse, mutect2, varscan2
